Somatic mutation profile of tumor specimen TCGA-AF-2693-01A (aliquot TCGA-AF-2693-01A-02D-1733-10) from TCGA case TCGA-AF-2693, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 75.1 years (27,443 days).
Specimen TCGA-AF-2693-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e39daf4-a74a-4491-9858-d8671be5da58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-2693-10A (Blood Derived Normal), aliquot TCGA-AF-2693-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c652eb0-1bc8-4a10-91e6-7611da6dbf12

The open-access MAF lists 97 somatic variants for this specimen: 72 protein-altering or splice-affecting, 24 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 24, Splice Site 6, Nonsense Mutation 6, Splice Region 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADS | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs199633532, CM067634, COSV54368245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2, varscan2
- ABCA10 | c.3426T>A p.N1142K | Missense Mutation (SNP) | VAF 71/274 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52226709; called by muse, mutect2, varscan2
- ADCY8 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53918280; called by muse, mutect2, varscan2
- ADGRB1 | c.1522T>A p.W508R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1252783918, COSV100029410; called by muse, mutect2
- ANKRD23 | c.298A>G p.K100E | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV58413041; called by muse, mutect2, varscan2
- APC | c.2055G>A p.W685* | Nonsense Mutation (SNP) | VAF 51/122 reads (42%) | catalogued as CM931177, COSV57399567; called by muse, mutect2, varscan2
- AXDND1 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.059); catalogued as rs778985705, COSV62639856; called by muse, mutect2, varscan2
- BCL9L | c.2536C>T p.Q846* | Nonsense Mutation (SNP) | VAF 34/62 reads (55%) | catalogued as COSV99420223; called by muse, mutect2, varscan2
- CDK20 | c.914G>A p.R305H (on ENST00000325303 / NM_001039803.3; = p.R284H on NM_012119.4) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs376253655; called by muse, mutect2, varscan2
- CDYL2 | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73654487; called by muse, mutect2, varscan2
- CFH | c.1271A>C p.K424T | Missense Mutation (SNP) | VAF 32/680 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV100661675; called by muse, mutect2
- CLEC18B | c.1181G>A p.S394N | Missense Mutation (SNP) | VAF 48/706 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100376159; called by muse, mutect2
- COL18A1 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV62704452; called by muse, mutect2, varscan2
- COL6A3 | c.4493C>T p.P1498L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs146629310; called by muse, mutect2, varscan2
- COMMD9 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as COSV54672923; called by muse, mutect2, varscan2
- COPS2 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54646480; called by muse, mutect2, varscan2
- CSMD3 | c.10922C>A p.A3641E (on ENST00000297405 / NM_001363185.1; = p.A3472E on NM_052900.3) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99849349; called by muse, mutect2, varscan2
- DYNC1I1 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs551953723, COSV61461198; called by muse, mutect2, varscan2
- EME2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV51601939; called by muse, mutect2
- GABRA5 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165230, COSV59477223; called by muse, mutect2, varscan2
- GALNT2 | c.566A>C p.K189T | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV64196418; called by muse, mutect2, varscan2
- GSE1 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1296183616, COSV53674198; called by muse, mutect2
- GTF3C1 | c.2048G>A p.G683D | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158681375, COSV62241347; called by muse, mutect2, varscan2
- HMCN1 | c.13634G>C p.C4545S | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99636612; called by muse, mutect2, varscan2
- HOXD10 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs761758159, COSV99982397; called by muse, mutect2
- IGF2 | c.461C>T p.P154L (on ENST00000434045 / NM_001127598.3; = p.P98L on NM_000612.6) | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs143785521; called by muse, varscan2
- IL19 | c.403A>G p.N135D | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.491); catalogued as COSV54284236; called by muse, mutect2, varscan2
- KDR | c.3685C>T p.R1229* | Nonsense Mutation (SNP) | VAF 45/100 reads (45%) | catalogued as rs763426023, COSV99817989; called by muse, mutect2, varscan2
- KMT5A | c.849C>T p.C283= | Splice Region (SNP) | VAF 33/104 reads (32%) | catalogued as rs752726590, COSV57864064; called by muse, mutect2, varscan2
- LAMB4 | c.4247C>A p.T1416K | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs775934990, COSV99223361, COSV99225818; called by muse, mutect2, varscan2
- LRRC59 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.531); catalogued as COSV56815125; called by muse, mutect2, varscan2
- MEAK7 | c.517A>G p.M173V | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1249455394, COSV59144914; called by muse, mutect2, varscan2
- NLRP13 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs748977496, COSV61621099, COSV61623198; called by muse, mutect2, varscan2
- NPBWR1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV58695452; called by muse, mutect2, varscan2
- OBSCN | c.9638C>T p.A3213V | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.49); catalogued as rs375877740, COSV52758076; called by muse, mutect2, varscan2
- OR2M4 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs531102387, COSV60708785, COSV60708977; called by muse, mutect2, varscan2
- OR51E2 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201184158, COSV67808196; called by muse, mutect2, varscan2
- OVCH2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs773982264, COSV71952995; called by muse, mutect2, varscan2
- PCDHB5 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.048); catalogued as rs1251535727, COSV50647140; called by muse, mutect2, varscan2
- PCDHGC5 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as rs1217345302, COSV52759510; called by muse, mutect2, varscan2
- PLA2G4C | c.1259C>A p.T420N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62786779; called by muse, mutect2, varscan2
- PRPSAP1 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.249); catalogued as rs1265289892, COSV61212040; called by muse, mutect2, varscan2
- PRRC2C | c.4532G>T p.R1511L (on ENST00000367742; = p.R1509L on NM_015172.4) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58909213, COSV58913976; called by muse, mutect2, varscan2
- PSMA3 | c.122G>T p.R41I | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53617817; called by muse, mutect2, varscan2
- PSMF1 | c.458G>T p.S153I | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV55675124; called by muse, mutect2, varscan2
- PTCHD3 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as COSV71257151; called by muse, mutect2, varscan2
- RAPH1 | c.540A>T p.K180N | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV57355558; called by muse, mutect2, varscan2
- RHOBTB3 | c.1763A>T p.N588I | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101183276; called by muse, mutect2
- RNF213 | c.2852A>G p.H951R | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.573); catalogued as rs746475303, COSV100174041; called by muse, mutect2, varscan2
- RYR2 | c.5588C>T p.T1863M | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs770863319, COSV63724318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S1PR3 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs778339232, COSV63980955; called by muse, mutect2, varscan2
- SLC12A6 | c.3228-1G>A p.X1076_splice (on ENST00000354181 / NM_001365088.1; = p.X1025_splice on NM_005135.2) | Splice Site (SNP) | VAF 35/116 reads (30%) | catalogued as COSV51628879; called by muse, mutect2, varscan2
- SPAG16 | c.797A>G p.Q266R | Missense Mutation (SNP) | VAF 108/306 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55988086; called by muse, mutect2, varscan2
- SPINT2 | c.553+1del p.X185_splice | Splice Site (DEL) | VAF 15/55 reads (27%) | catalogued as COSV56648438; called by mutect2, pindel, varscan2
- TAF5 | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 35/193 reads (18%) | catalogued as rs767666893, COSV60857561; called by muse, mutect2, varscan2
- TDRD3 | c.689T>A p.L230H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52160609; called by muse, mutect2
- TEAD4 | c.997A>T p.K333* | Nonsense Mutation (SNP) | VAF 25/91 reads (27%) | catalogued as COSV63281828; called by muse, mutect2, varscan2
- TJAP1 | c.19G>C p.A7P | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV52502556; called by muse, mutect2, varscan2
- TLR8 | c.838C>A p.R280S (on ENST00000218032 / NM_138636.5; = p.R298S on NM_016610.4) | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1255043567, COSV54319305, COSV54319446; called by muse, mutect2, varscan2
- TMEM132B | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54757496, COSV54762045; called by muse, mutect2, varscan2
- TNIP2 | c.1027-1G>A p.X343_splice | Splice Site (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100198733, COSV59569796; called by muse, mutect2, varscan2
- TRAPPC13 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV51559332; called by muse, mutect2, varscan2
- TRPM8 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as rs200707338, COSV61222141; called by muse, mutect2, varscan2
- TTN | c.3377A>G p.Y1126C (on ENST00000591111; = p.Y1080C on NM_003319.4) | Missense Mutation (SNP) | VAF 49/160 reads (31%) | PolyPhen probably damaging (0.999); catalogued as COSV60212958; called by muse, mutect2, varscan2
- TUBE1 | c.1272T>C p.A424= | Splice Region (SNP) | VAF 28/64 reads (44%) | catalogued as COSV100037223; called by muse, mutect2
- UBE2C | c.217-5G>A | Splice Region (SNP) | VAF 14/194 reads (7%) | catalogued as COSV54755283; called by muse, mutect2
- ZFX | c.796+2T>G p.X266_splice | Splice Site (SNP) | VAF 62/98 reads (63%) | catalogued as COSV58449126; called by muse, mutect2, varscan2
- ZNF217 | c.2596G>A p.V866I | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56600285; called by muse, mutect2, varscan2
- ZNF665 | c.458G>A p.R153H (on ENST00000600412; = p.R218H on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs761307195, COSV67214252, COSV67215257; called by muse, mutect2, varscan2
- FRYL | c.4126-1G>A p.X1376_splice | Splice Site (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- PKHD1L1 | c.5216G>A p.C1739Y | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ABCA6 | c.4461G>T p.V1487= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as COSV52641963; called by muse, mutect2, varscan2
- ADGRV1 | c.12846G>A p.Q4282= | Silent (SNP) | VAF 51/152 reads (34%) | catalogued as COSV67978101; called by muse, mutect2, varscan2
- BIRC6 | c.2892C>T p.L964= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs960038337, COSV70203326; called by muse, mutect2, varscan2
- COL5A1 | c.1044G>A p.T348= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs1246095864, COSV65666267; ClinVar: likely benign; called by muse, mutect2, varscan2
- ETV5 | c.771G>A p.P257= | Silent (SNP) | VAF 21/211 reads (10%) | catalogued as rs370362112; called by muse, mutect2
- FCHSD1 | c.2034T>A p.A678= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV51838127; called by muse, mutect2, varscan2
- FNDC3B | c.2490T>A p.A830= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV61046443; called by muse, mutect2, varscan2
- GRM2 | c.1755G>A p.V585= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV56586226; called by muse, mutect2, varscan2
- KCNIP1 | c.666G>A p.L222= (on ENST00000411494 / NM_001034837.3; = p.L211= on NM_014592.4) | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs1407646435, COSV61087806; called by muse, mutect2, varscan2
- LCE1D | c.306C>T p.C102= | Silent (SNP) | VAF 192/568 reads (34%) | catalogued as rs777534260, COSV100405961; called by muse, varscan2
- MAD1L1 | c.2148C>T p.T716= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs774776172, COSV56241377; called by muse, mutect2, varscan2
- NINL | c.336G>T p.R112= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV99626463; called by muse, mutect2, varscan2
- PCDHA12 | c.1566G>A p.P522= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV56518249; called by muse, mutect2, varscan2
- PCDHB7 | c.1023C>T p.N341= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs1554280068, COSV50760872; called by muse, mutect2, varscan2
- PCSK6 | c.897C>T p.I299= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs762240584, COSV59340643, COSV59344033; called by muse, mutect2, varscan2
- PLB1 | c.3741C>T p.F1247= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs747453824, COSV59819067, COSV59831632; called by muse, mutect2, varscan2
- PXDNL | c.1704C>T p.Y568= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs950735336, COSV62480026; called by muse, mutect2
- SEMA4D | c.1545G>A p.A515= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs762000415, COSV59398181; called by muse, mutect2, varscan2
- SPATA9 | c.681G>A p.K227= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV57224731; called by muse, mutect2, varscan2
- SS18L1 | c.795G>A p.E265= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV59212135; called by muse, mutect2
- STRA6 | c.33C>T p.S11= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as COSV60587528; called by muse, mutect2, varscan2
- TMEM63C | c.1626C>T p.G542= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as rs758029187, COSV53602332; called by muse, mutect2, varscan2
- TNS1 | c.1107G>A p.V369= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as COSV50733287; called by muse, mutect2, varscan2
- TRPC1 | c.282C>T p.N94= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs770645332, COSV56427752; called by muse, mutect2, varscan2
- CPLANE1 | c.*4985C>T | 3'UTR (SNP) | VAF 64/196 reads (33%) | catalogued as rs768454790, COSV57050940, COSV57053745; called by muse, mutect2, varscan2
